Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8P2, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8P2-01A (Primary Tumor).

[page 1 of 2]
Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

- 1 - "Chain 6 lymph node":
Adipose and connective tissue uninvolved by neoplasia.
- 2 - "Chain 13 lymph node":
Adipose and connective tissue uninvolved by neoplasia.
- 3 - "Chain 12 lymph node":
Adipose and connective tissue uninvolved by neoplasia.
- 4 - "Chain 8 lymph node":
Adipose and connective tissue uninvolved by neoplasia.
- 5 - "Chain 1 Lymph node":
Skeletal muscle tissue uninvolved by neoplasia.
- 6 - "Chain 11 lymph node":
Lymph node uninvolved by neoplasia (0/1).
- 7 - "11d chain lymph node":
Lymph node uninvolved by neoplasia (0/1).
- 8 - "Chain 16a lymph node":
Two lymph nodes uninvolved by neoplasia (0/2).
- 9 - "Vagus Nerve":
Nerve and adipose tissue uninvolved by neoplasia.
- 10 - "Esophageal margin":
Absence of neoplasia.
- 11 - "Jejune":
Small intestine with no particularities.
- 12 - "Gallbladder":
Chronic cholecystitis.
- 13 - "Duodenal margin 1":
Absence of neoplasia.
- 14 - "Duodenal margin 2":
Absence of neoplasia.
- 15 - "Stomach + duodenum + esophagus + omentum":
Moderately differentiated mucinous adenocarcinoma
Level of infiltration: perigastric adipose tissue.
Bormann Classification: Type III
Surgical resection margins uninvolved by neoplasia.
Presence of lymphatic embolization.
Absence of blood vascular or perineural invasion.
Presence of neoplastic node in the adipose tissue.
Metastasis in 1 of 12 resected lymph nodes with extracapsular extension (1/12).

ICD O 3
Adenocarcinoma, mucinous
8480/3
Site Body, stomach
016.2
720 3/7/14

[page 2 of 2]
16 - "Left axillary lymph node":
Seven lymph nodes uninvolved by neoplasia (0/7).

Criteria	11/11/13	Yes	No
Staging Discrepancy			✓
Prior Biopsy History			✓
Quasi-Synchronous Primary Neoplasm			✓
Case is (re)filed			

Source: NCI Genomic Data Commons file 2a40a5f3-e0b2-4b6f-8f61-36746d7c49c3 (TCGA-VQ-A8P2.7E738C8E-25E5-49DC-ABA4-2C7DD768B775.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).